Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A3NZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A3NZ-01A (Primary Tumor).

[page 1 of 3]
FINAL DIAGNOSIS

- A) Left thyroid lobe and isthmus: Papillary thyroid carcinoma forming a 3.5 cm in greatest dimension tumor mass. The thyroid carcinoma focally invades through the capsule into the extracapsular soft tissue. Inked surgical margins of resection are free of tumor. Areas of chronic thyroiditis are also noted.
- B) Left paratracheal nodes: Metastatic papillary thyroid carcinoma involving one out of one lymph node (1/1).
- C) Pretracheal lymph nodes: Metastatic papillary thyroid carcinoma involving one out of seven lymph nodes (1/7).
- D) Right thyroid lobe: Benign thyroid tissue showing chronic inflammation with intrathyroidal parathyroid tissue. Benign lymph node without evidence of tumor.

A: Thyroid Gland

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR FOCALITY:

Unifocal

Left lobe

ICD 0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, nos C73.9 lu

2/6/12

TUMOR SIZE:

Greatest Dimension: 3.5 cm

HISTOLOGIC GRADE:

G1: Well differentiated

PRIMARY TUMOR (pT):

pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)

REGIONAL LYMPH NODES (pN):

pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes

NUMBER OF LYMPH NODE(S) INVOLVED: 2

[page 2 of 3]
NUMBER OF LYMPH NODE(S) EXAMINED: 9
LYMPH NODE, EXTRANODAL EXTENSION:
Not identified

DISTANT METASTASIS (pM):
Not applicable

MARGINS:
Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION
EXTRATHYROIDAL EXTENSION:
Present
Minimal

ADDITIONAL PATHOLOGIC FINDINGS:
Thyroiditis:
Focal (nonspecific)

~electronic signature~

SPECIMEN RECEIVED

- A) LEFT THYROID LOBE AND ISTHMUS, FS
- B) LEFT PARATRACHEAL NODES
- C) PRETRACHEAL LYMPH NODES
- D) RIGHT THYROID LOBE

FROZEN SECTION

A1) Left thyroid lobe and isthmus: Papillary thyroid carcinoma (3.5 cm).

GROSS DESCRIPTION

A) Received fresh for frozen section labeled "left thyroid lobe and isthmus" is an 18-gram lobe of thyroid lobe and isthmus, measuring overall approximately 4.8 x 4.1 x 2.5 cm. The specimen is inked on its surgical margins. Sectioning reveals an indurated gray/tan to pink/tan nodule in the superior pole, measuring approximately 3.5 cm in greatest dimension. Touch preps are made. A representative section of the nodule is submitted for frozen section as A1. The nodule grossly appears to be completely excised. Sectioning through the remainder of the specimen reveals a

[page 3 of 3]
red/tan nodule in the inferior pole, measuring 0.5 cm in greatest dimension. This does not grossly appear suspicious. Permanent sections are submitted as follows: Larger nodule A2-A4, smaller nodule A5, and random thyroid A6. Tissue is also collected for the thyroid tissue registry protocol.

B) The specimen is labeled "left paratracheal nodes" and consists of a lymph node measuring 0.8 cm in greatest dimension. It is bisected and completely embedded along with a small portion of fatty tissue labeled B1.

C) The specimen is labeled "pretracheal lymph node" and consists of an irregular fragment of tan/yellow tissue measuring 2.5 x 1.0 x 1.0 cm. A definitive lymph node is not identified. The specimen is entirely submitted as C1.

D) The specimen is labeled "right thyroid lobe" and consists of the right lobe of the thyroid measuring 5.0 x 3.5 x 1.7 cm. The specimen is serially sectioned and reveals beefy red parenchyma without any distinct lesions. The specimen is sampled and labeled D1 through D6.

CLINICAL INFORMATION

THYROID NODULE

Source: NCI Genomic Data Commons file b4e25316-18f0-491d-9550-3bdf7b5dcf97 (TCGA-J8-A3NZ.0C81E059-8C59-4197-825E-19E5A3AF9372.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).